Somatic mutation profile of tumor specimen TCGA-B0-5081-01A (aliquot TCGA-B0-5081-01A-01D-1462-08) from TCGA case TCGA-B0-5081, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 80.0 years (29,219 days).
Specimen TCGA-B0-5081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a00c1c2b-67a0-4dd0-ad82-e8777035729e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5081-11A (Solid Tissue Normal), aliquot TCGA-B0-5081-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b77b9ee0-65f6-4575-ab60-95e0664476d5

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 29, Silent 10, Nonsense Mutation 4, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131690962, CM003060, COSV104374386, COSV56542402, COSV56545166; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARSF | c.124A>T p.I42F | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV63841091; called by muse, mutect2, varscan2
- CARD11 | c.2900G>C p.R967P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV101210414, COSV67802575; called by muse, mutect2, varscan2
- CCDC80 | c.942C>G p.D314E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52819994; called by muse, mutect2, varscan2
- CCR6 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs113115632, COSV59476239; called by muse, mutect2
- CD34 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60415204; called by muse, mutect2
- COL15A1 | c.3433C>A p.L1145M | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.49); catalogued as COSV66649285; called by muse, mutect2, varscan2
- COL15A1 | c.3434T>A p.L1145Q | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV66649289; called by muse, mutect2, varscan2
- COL6A6 | c.3884G>A p.R1295Q | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs770183659, COSV62038048; called by muse, mutect2
- FAM83B | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60926928; called by muse, mutect2, varscan2
- FLG | c.10228A>T p.R3410* | Nonsense Mutation (SNP) | VAF 36/342 reads (11%) | catalogued as COSV64249528; called by muse, mutect2, varscan2
- IL6ST | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61142985; called by muse, mutect2
- IRX2 | c.1108T>A p.S370T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.115); catalogued as COSV57413748; called by muse, mutect2, varscan2
- JCAD | c.2673G>T p.E891D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.423); catalogued as COSV64761721; called by muse, mutect2
- LGR5 | c.1819G>T p.G607* | Nonsense Mutation (SNP) | VAF 9/109 reads (8%) | catalogued as COSV99878209; called by muse, mutect2
- MMAB | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57171205; called by muse, mutect2, varscan2
- NCL | c.965A>G p.E322G | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100502416; called by muse, mutect2
- NOX1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54196663; called by muse, mutect2
- OCRL | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV63981556; called by muse, mutect2, varscan2
- OR8B8 | c.479C>A p.T160K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV60145813; called by muse, mutect2, varscan2
- PBRM1 | c.4933G>T p.E1645* (on ENST00000296302 / NM_001366071.2; = p.E1538* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | catalogued as COSV99970053; called by muse, mutect2
- PCDHB2 | c.2233G>C p.G745R | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.341); catalogued as COSV99164296; called by muse, mutect2
- PELO | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50899012; called by muse, mutect2
- PLA2G4E | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs189961279, COSV68151261; called by muse, mutect2
- PLEKHA4 | c.361T>G p.F121V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99612902; called by muse, mutect2
- POLR2A | c.5030G>A p.S1677N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.383); catalogued as rs1225656237; called by muse, mutect2, varscan2
- PYDC2 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72921495; called by muse, varscan2
- SENP6 | c.588A>T p.Q196H | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59194725; called by muse, mutect2
- SETD2 | c.2181C>A p.C727* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as COSV57452192; called by muse, mutect2
- SVEP1 | c.1352G>T p.C451F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57048167; called by muse, mutect2
- USP47 | c.3127G>A p.E1043K (on ENST00000399455 / NM_001372095.1; = p.E955K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV60468102; called by muse, mutect2
- ZNF280B | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV100840234, COSV64529700; called by muse, mutect2, varscan2
- ZNF668 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317182087, COSV56219297; called by mutect2, varscan2
- IRF3 | c.1148del p.G383Vfs*71 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel, varscan2
- NEXMIF | c.2170del p.S724Vfs*5 | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel
- PBRM1 | c.3404del p.P1135Lfs*24 (on ENST00000296302 / NM_001366071.2; = p.P1110Lfs*24 on NM_018313.5) | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- AACS | c.1467G>A p.K489= | Silent (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- AQP12A | c.117G>C p.R39= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV61837748, COSV61837858; called by muse, mutect2
- CCDC51 | c.442T>C p.L148= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV56491682; called by muse, mutect2
- CNR1 | c.504C>A p.V168= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100759277; called by muse, mutect2, varscan2
- DCC | c.3838C>A p.R1280= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs747698662, COSV101473412; called by muse, mutect2, varscan2
- EDC4 | c.192T>A p.T64= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs544508740, COSV54647165, COSV54647490; called by muse, mutect2, varscan2
- NIPA1 | c.912G>C p.G304= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV61680754; called by muse, mutect2
- RHOT2 | c.552G>A p.A184= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs775471054, COSV53475388; called by muse, mutect2, varscan2
- TTN | c.100743G>A p.R33581= (on ENST00000591111; = p.R26157= on NM_003319.4) | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as COSV60354550; called by muse, mutect2
- USH2A | c.2919A>G p.Q973= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs138484134, COSV56354170; called by muse, mutect2, varscan2
